Gene-level copy-number profile of tumor specimen C3N-02000-01 (profiled together with C3N-02000-02) from CPTAC case C3N-02000, project CPTAC-3 (Bronchus and lung — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IIA; Tumor grade: G2; Age at diagnosis: 46.3 years (16,924 days).
Specimen C3N-02000-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file b89ba0b1-1203-462c-bf42-78c30af67372.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3N-02000-71 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,218 have no estimate.
https://portal.gdc.cancer.gov/files/cf8c6bb3-16a3-4674-a45d-705772217265

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 17; copy number 1: 1,394; copy number 2: 22,550; copy number 3: 23,805; copy number 4: 7,144; copy number 5: 2,764; copy number 6: 231; copy number 7: 119; copy number 8: 192; copy number 9: 30; copy number 10: 19; copy number 11: 139; copy number 16: 1.

Homozygous deletions (total copy number 0; autosomes only): 17 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:61,190,003–61,662,690, 11 genes: SPATA31A7, BX005040.3, BX005040.2, FAM74A4, BX005040.1, CNTNAP3C, RN7SL462P, AL935212.3, FAM242D, Y_RNA, AL935212.1.
- chr22:18,533,646–18,611,919, 4 genes: PI4KAP1, AC023490.1, RN7SKP131, RIMBP3.
- chr22:18,623,339–18,638,405, 2 genes: SUSD2P2, CA15P2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 2,843 genes in 22 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:1,352,689–2,547,460, 61 genes, copy number 5–10 (broad region; genes not listed).
- chr1:3,069,168–3,438,621, 2 genes, copy number 7 (within-gene range 4–7): PRDM16, MIR4251.
- chr1:3,205,988–3,373,928, 4 genes, copy number 7: AL512383.1, AL590438.1, AL354743.2, AL354743.1.
- chr2:96,208,403–97,739,862, 59 genes, copy number 5 (within-gene range 3–5): STARD7-AS1, TMEM127, CIAO1, SNRNP200, AC021188.1, ITPRIPL1, NCAPH, NEURL3, AC013270.1, ARID5A, KANSL3, FER1L5, LMAN2L, CNNM4, MIR3127, CNNM3-DT, CNNM3, ANKRD23, ANKRD39, SEMA4C, FAM178B, AC092636.1, Metazoa_SRP, RNA5SP101, AC079395.3, AC079395.2, AC079395.1, TRIM43CP, AC018892.1, AC018892.2, IGKV2OR2-1, IGKV2OR2-2, IGKV1OR2-3, GPAT2P2, FAHD2B, AC018892.3, RN7SL313P, ANKRD36, AC159540.2, AC159540.1, IGKV1OR2-9, IGKV2OR2-10, IGKV2OR2-7D, IGKV3OR2-5, IGKV1OR2-6, IGKV2OR2-7, IGKV2OR2-8, IGKV1OR2-11, AC092683.1, AC092683.2, ANKRD36B, AC017099.1, AC017099.2, UBTFL6, COX5B, ACTR1B, C2orf92, RNU4-8P, ZAP70.
- chr5:140,664,676–141,329,357, 66 genes, copy number 8 (broad region; genes not listed).
- chr5:141,350,109–141,350,662, 1 gene, copy number 8: AC005618.3.
- chr5:165,782,805–165,783,134, 1 gene, copy number 10: AC008562.1.
- chr5:166,028,567–166,382,599, 3 genes, copy number 9–16: RPL7P20, AC114321.1, AC026403.1.
- chr5:167,284,799–168,264,157, 1 gene, copy number 5 (within-gene range 3–5): TENM2.
- chr5:167,937,717–176,034,680, 144 genes, copy number 5 (broad region; genes not listed).
- chr7:182,935–1,747,954, 45 genes, copy number 5–7: AC093627.3, FAM20C, AC145676.1, FOXL3, AC226118.1, AC147651.1, PDGFA, HRAT92, PRKAR1B, PRKAR1B-AS2, PRKAR1B-AS1, DNAAF5, SUN1, GET4, AC073957.3, ADAP1, COX19, CYP2W1, C7orf50, MIR339, AC073957.1, GPR146, AC073957.2, AC091729.1, AC091729.2, GPER1, ZFAND2A, ZFAND2A-DT, UNCX, AC073094.1, MICALL2, AC102953.1, AC102953.2, INTS1, AC093734.1, MAFK, TMEM184A, PSMG3, PSMG3-AS1, TFAMP1, AC074389.2, ELFN1, AC074389.3, AC074389.1, ELFN1-AS1.
- chr7:1,838,586–1,849,931, 2 genes, copy number 7 (within-gene range 2–7): AC104129.1, MIR4655.
- chr7:14,145,049–14,974,777, 1 gene, copy number 6 (within-gene range 2–6): DGKB.
- chr7:14,814,131–16,784,536, 23 genes, copy number 6: AC006150.1, GTF3AP5, AC006458.1, AGMO, MEOX2, AC005550.2, LINC02587, AC005550.1, RPL36AP26, AC006041.1, CRPPA, RPL36AP29, CRPPA-AS1, SOSTDC1, AC005014.3, LRRC72, AC005014.1, AC005014.2, ANKMY2, AC005014.4, BZW2, AC073333.1, TSPAN13.
- chr7:18,086,949–33,877,180, 285 genes, copy number 5–11 (within-gene range 3–11) (broad region; genes not listed).
- chr7:35,800,932–56,603,553, 366 genes, copy number 5–11 (broad region; genes not listed).
- chr8:41,929,479–145,066,685, 1,551 genes, copy number 5 (broad region; genes not listed).
- chr9:63,802,144–64,082,534, 7 genes, copy number 5: CR786580.1, RNA5SP284, DUX4L50, MIR4477B, FRG1JP, AL163540.1, U6.
- chr12:12,310–442,642, 16 genes, copy number 5: DDX11L8, WASH8P, FAM138D, IQSEC3, AC026369.3, AC026369.1, AC026369.2, AC007406.3, SLC6A12, AC007406.1, SLC6A12-AS1, SLC6A13, AC007406.2, AC007406.4, KDM5A, CCDC77.
- chr14:29,952,397–36,679,362, 132 genes, copy number 5–11 (within-gene range 4–11) (broad region; genes not listed).
- chr20:35,172,072–36,951,843, 66 genes, copy number 5–6 (broad region; genes not listed).
- chr20:53,544,615–53,875,557, 7 genes, copy number 5: Y_RNA, AL157838.1, ZNF217, AC005808.1, RNU7-14P, AC006076.1, SUMO1P1.

Autosomal genes at a single copy (total copy number 1): 1,394. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
